Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4700, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4700-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

RIGHT KIDNEY AND ADRENAL GLAND, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH AREAS OF HEMORRHAGE AND NECROSIS AND FOCAL SARCOMATOID DEDIFFERENTIATION (SECTION 1H), FUHRMAN'S NUCLEAR GRADE 4 OF 4 IN HIGHEST GRADE AREAS (14 CM IN MAXIMAL DIMENSION). CARCINOMA EPICENTER IS IN THE UPPER POLE OF THE KIDNEY.
- B. CARCINOMA INVADIES INTO THE PERINEPHRIC ADIPOSE TISSUE AND INVOLVES THE RENAL PELVIS / SINUS.
- C. CARCINOMATOUS ANGIOLYMPHATIC INVASION OF SMALL VESSELS IS IDENTIFIED (SECTIONS 1C, 1E).
- D. EXTRA-RENAL RENAL CELL CARCINOMA CLOSELY APPROACHES BUT DOES NOT INVOLVE THE ADRENAL GLAND (SECTION 1H).
- E. PROXIMAL URETER, MAIN RENAL ARTERY AND MAIN RENAL VEIN SEGMENTS ARE BENIGN.
- F. RENAL CELL CARCINOMA IS PRESENT AT THE PERINEPHRIC SURGICAL RESECTION MARGIN IN THE REGION OF THE UPPER POLE (parts 2 and 3).
- G. NON-NEOPLASTIC KIDNEY SHOWS NO SIGNIFICANT PATHOLOGIC CHANGES.
- H. PATHOLOGIC TNM STAGE: pT4 Nx Mx (see comment).

PART 2:

UPPER POLE MARGIN, EXCISION -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH FOCAL SARCOMATOID DE-DIFFERENTIATION. CARCINOMA INVOLVES MOST OF THE TISSUE SUBMITTED.
- B. SMALL FRAGMENT OF SKELETAL MUSCLE WITH DEGENERATIVE CHANGES.

PART 3:

PERI-DIAPHRAGMATIC TISSUE, EXCISION -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH FOCAL SARCOMATOID DE-DIFFERENTIATION. CARCINOMA INVOLVES MOST OF THE TISSUE SUBMITTED.
- B. SMALL FRAGMENT OF SKELETAL MUSCLE WITH DEGENERATIVE CHANGES, ADJACENT TO THE TUMOR.

COMMENT:

Part 1: The assigned pathologic T stage is based on the presence of contiguous renal cell carcinoma outside the Gerota's fascia, adjacent to skeletal muscle.

Source: NCI Genomic Data Commons file fb0e72b5-8ba8-4d4e-8548-45ff4e87399f (TCGA-B0-4700.8AA37C12-4070-4AC3-AA59-184C93327BDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).